CPTAC case C3L-04331 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5a61a3e-2e35-40c2-aa83-5f90040dfc53

Demographics
Sex at birth: male; Race: white; Year of birth: 1931; Vital status: Dead; Days to death: 364 days; Year of death: 2019; Cause of death: Cardiovascular Disorder, NOS; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 87.7 years (32,040 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 364 days; Progression or recurrence: no; Days to last follow up: 269 days; Tumor focality: Multifocal; Ulceration indicator: No.
   Pathology details: Greatest tumor dimension: 4.6 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 3; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 269 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04331-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 443 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04331-21: Section location: Lymph node; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-04331-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
